Somatic mutation profile of tumor specimen ALCH-ADJ4-TTP1-A (aliquot ALCH-ADJ4-TTP1-A-1-0-D-A532-36) from ALCHEMIST case ALCH-ADJ4, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 69.1 years (25,255 days).
Specimen ALCH-ADJ4-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9c3f18a7-25af-44a7-a9fa-c68ed76dfd3b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-ADJ4-NB1-A (Blood Derived Normal), aliquot ALCH-ADJ4-NB1-A-2-1-D-A532-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2c342504-17f4-40fe-aa9c-6a294e74321d

The open-access MAF lists 44 somatic variants for this specimen: 26 protein-altering or splice-affecting, 13 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 13, Splice Site 3, Intron 2, 3'UTR 2, In Frame Del 1, 5'UTR 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2235_2249del p.E746_A750del | In Frame Del (DEL) | VAF 150/931 reads (16%) | hotspot (GDC flag); catalogued as rs121913421, COSV51765119; ClinVar: drug response; called by mutect2, pindel, varscan2
- ACTL7B | c.476A>T p.N159I | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV65928210; called by muse, mutect2, varscan2
- DCAF4L1 | c.773G>A p.R258Q | Missense Mutation (SNP) | VAF 17/159 reads (11%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs553184430; called by muse, mutect2
- DDX42 | c.1472G>A p.R491H | Missense Mutation (SNP) | VAF 45/802 reads (6%) | SIFT tolerated (0.29); PolyPhen benign (0.01); catalogued as rs143293246; called by muse, mutect2
- FBN2 | c.2111G>C p.S704T | Missense Mutation (SNP) | VAF 36/328 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV52534875; called by muse, mutect2, varscan2
- GNA14 | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 38/584 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.111); catalogued as rs756624939, COSV59020348; called by muse, mutect2
- ITGA6 | c.1930C>T p.P644S (on ENST00000442250; = p.P605S on NM_000210.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 56/816 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99905203; called by muse, mutect2
- TACC3 | c.1153G>A p.D385N | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs755526449; called by muse, mutect2
- TP53 | c.75-1G>T p.X25_splice | Splice Site (SNP) | VAF 54/432 reads (13%) | catalogued as COSV53294543, COSV99037345; called by muse, mutect2, varscan2
- AMPH | c.1216-1G>A p.X406_splice | Splice Site (SNP) | VAF 25/185 reads (14%) | called by muse, mutect2, varscan2
- AVEN | c.766G>T p.G256C | Missense Mutation (SNP) | VAF 11/208 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2
- CATSPER1 | c.1521C>G p.F507L | Missense Mutation (SNP) | VAF 21/403 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); called by muse, mutect2
- COMMD9 | c.362C>T p.P121L | Missense Mutation (SNP) | VAF 25/180 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EBF3 | c.783C>A p.A261= (on ENST00000355311 / NM_001375392.1; = p.A252= on NM_001005463.3 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 11/95 reads (12%) | called by muse, mutect2
- ILF2 | c.202T>G p.S68A | Missense Mutation (SNP) | VAF 60/374 reads (16%) | SIFT tolerated (0.5); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MREG | c.71T>A p.L24Q | Missense Mutation (SNP) | VAF 12/186 reads (6%) | SIFT tolerated (0.58); PolyPhen benign (0.082); called by muse, mutect2
- NOMO1 | c.1807-1G>C p.X603_splice | Splice Site (SNP) | VAF 37/582 reads (6%) | called by muse, mutect2
- PATE1 | c.321T>A p.S107R | Missense Mutation (SNP) | VAF 45/251 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.79); called by muse, varscan2
- PNLIPRP3 | c.254C>A p.T85K | Missense Mutation (SNP) | VAF 34/376 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.015); called by muse, mutect2
- SLC6A13 | c.560G>T p.W187L | Missense Mutation (SNP) | VAF 10/194 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); called by muse, mutect2
- SLITRK6 | c.1357G>A p.G453R | Missense Mutation (SNP) | VAF 43/239 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- STAG2 | c.1088A>G p.K363R | Missense Mutation (SNP) | VAF 11/243 reads (5%) | SIFT tolerated (0.63); PolyPhen benign (0.001); called by muse, mutect2
- TAS2R41 | c.901G>A p.A301T | Missense Mutation (SNP) | VAF 28/129 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.09); called by muse, varscan2
- USE1 | c.385G>C p.D129H | Missense Mutation (SNP) | VAF 26/230 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.006); called by muse, mutect2
- ZNF462 | c.383G>A p.R128K | Missense Mutation (SNP) | VAF 16/428 reads (4%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.137); called by muse, mutect2
- ZNF781 | c.782A>C p.N261T | Missense Mutation (SNP) | VAF 41/130 reads (32%) | SIFT tolerated (0.51); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- CYP2D6 | c.933G>A p.S311= | Silent (SNP) | VAF 30/361 reads (8%) | catalogued as rs201297021, COSV62244489; called by muse, mutect2
- DLG2 | c.1563C>T p.N521= | Silent (SNP) | VAF 101/653 reads (15%) | called by muse, mutect2, varscan2
- FEM1A | c.1524G>A p.V508= | Silent (SNP) | VAF 12/262 reads (5%) | called by muse, mutect2
- GALNT6 | c.693C>T p.Y231= | Silent (SNP) | VAF 22/111 reads (20%) | catalogued as rs753279952, COSV62541880; called by muse, mutect2, varscan2
- GNE | c.2055G>A p.V685= (on ENST00000396594 / NM_001128227.3; = p.V654= on NM_005476.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 48/426 reads (11%) | called by muse, mutect2, varscan2
- IQCJ-SCHIP1 | c.246G>A p.L82= | Silent (SNP) | VAF 50/273 reads (18%) | catalogued as rs1279900557; called by muse, mutect2, varscan2
- KLHDC8A | c.780A>T p.R260= | Silent (SNP) | VAF 14/338 reads (4%) | called by muse, mutect2
- MALRD1 | c.6108T>C p.C2036= | Silent (SNP) | VAF 25/264 reads (9%) | catalogued as rs1183185746; called by muse, mutect2, varscan2
- NOMO1 | c.1701G>A p.K567= | Silent (SNP) | VAF 60/876 reads (7%) | called by muse, mutect2
- OR52E2 | c.531C>T p.P177= | Silent (SNP) | VAF 11/86 reads (13%) | called by muse, mutect2, varscan2
- UBR2 | c.1191G>A p.Q397= | Silent (SNP) | VAF 14/304 reads (5%) | called by muse, mutect2
- VKORC1 | c.378C>T p.F126= | Silent (SNP) | VAF 56/425 reads (13%) | catalogued as rs200313404, COSV54925083; called by muse, mutect2, varscan2
- ZNF808 | c.2649C>T p.A883= | Silent (SNP) | VAF 16/125 reads (13%) | called by muse, mutect2, varscan2
- FAM83F | c.*18G>A | 3'UTR (SNP) | VAF 13/144 reads (9%) | catalogued as rs1332786537; called by muse, mutect2
- SUPT16H | c.66+191C>T | Intron (SNP) | VAF 7/44 reads (16%) | catalogued as rs1053472100; called by muse, mutect2, varscan2
- TCF3 | c.1823-435C>T | Intron (SNP) | VAF 9/48 reads (19%) | catalogued as rs759261756, COSV99514523; called by muse, mutect2, varscan2
- WDR90 | c.*68C>T | 3'UTR (SNP) | VAF 15/156 reads (10%) | catalogued as rs1376403234; called by muse, mutect2, varscan2
- ZNF479 | c.-5G>T | 5'UTR (SNP) | VAF 106/400 reads (27%) | called by muse, mutect2, varscan2
